Gene-level copy-number profile of tumor specimen TCGA-W5-AA30-01A from TCGA case TCGA-W5-AA30, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 82.2 years (30,039 days).
Specimen TCGA-W5-AA30-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CHOL.feba63a7-a670-475f-8077-9739e0bf30f8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-W5-AA30-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c33ea7d1-28c1-46c6-a954-e75ec77a34ab

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 16,762; copy number 3: 9,549; copy number 4: 24,755; copy number 5: 3,028; copy number 6: 2,862; copy number 7: 935; copy number 8: 93; copy number 9: 1,592; copy number 10: 11; copy number 11: 1; copy number 12: 29; copy number 14: 169; copy number 15: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-W5-AA30-01A-31D-A416-01): tumor purity 0.52, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,833 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–207,917,088, 1,723 genes, copy number 9–14 (broad region; genes not listed).
- chr3:77,811,741–79,767,998, 11 genes, copy number 10 (within-gene range 7–10): RNU6-217P, LINC02077, AC117462.1, RN7SL647P, RN7SKP61, AC108752.1, MRPS17P3, ROBO1, AC055731.1, RN7SL751P, AC117461.1.
- chr3:83,384,445–84,051,419, 4 genes, copy number 9: AC023503.1, AC092825.1, SRRM1P2, AC117464.1.
- chr3:85,385,710–85,385,792, 1 gene, copy number 11: MIR5688.
- chr6:66,093,431–66,094,909, 1 gene, copy number 14: NUFIP1P1.
- chr6:67,210,408–68,635,161, 16 genes, copy number 14: AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1.
- chr11:69,147,228–69,819,416, 17 genes, copy number 9: AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3.
- chr13:105,410,816–110,136,906, 60 genes, copy number 12–15: AL138954.1, DAOA-AS1, AL359751.2, AL359751.1, DAOA, AL359745.1, LINC00343, AL138701.1, AL138701.2, RNA5SP38, AL139379.1, LINC00460, RPL35P9, EFNB2, AL138689.2, AL138689.1, ARGLU1, LINC00551, LINC00443, ATP5MC1P5, AL163534.1, AL162574.2, PPIAP24, AL162574.1, AL162574.3, AL354741.1, FAM155A, SNORD31B, AL445649.1, MIR1267, FAM155A-IT1, AL359436.1, AL136964.1, LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, AL138694.1, HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, AL390755.3.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
